Somatic mutation profile of tumor specimen TCGA-CH-5739-01A (aliquot TCGA-CH-5739-01A-11D-1576-08) from TCGA case TCGA-CH-5739, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.6 years (23,953 days).
Specimen TCGA-CH-5739-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad6b269e-9164-4069-bba1-d358584b1eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5739-10A (Blood Derived Normal), aliquot TCGA-CH-5739-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8630dc7c-2596-4841-949b-c781e4c96cff

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1241680643, COSV56806892; called by muse, mutect2, varscan2
- CRNN | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200128647, COSV55122292; called by muse, mutect2, varscan2
- FAM126B | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV53773613; called by muse, mutect2, varscan2
- FAM47B | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV61452974; called by muse, mutect2, varscan2
- GJA5 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1553227026, COSV54785041; called by muse, mutect2, varscan2
- IGDCC4 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | catalogued as rs138576438; called by muse, mutect2, varscan2
- LCE1A | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs777339865, COSV58727066, COSV58727546; called by muse, mutect2, varscan2
- LCE1C | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV64218737; called by muse, mutect2, varscan2
- LRCH1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 86/173 reads (50%) | catalogued as COSV60849499; called by muse, mutect2, varscan2
- LRIT2 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs372043491; called by muse, mutect2, varscan2
- MRGPRX3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs551318965, COSV66934227; called by muse, mutect2
- MUC16 | c.43441C>T p.R14481W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs747851309, COSV66690868; called by muse, mutect2, varscan2
- MYH15 | c.4927T>A p.C1643S | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV56313780; called by muse, mutect2, varscan2
- NCAPG2 | c.1991A>T p.D664V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51989185; called by muse, mutect2, varscan2
- PTGFRN | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140355100, COSV67798976; called by muse, mutect2, varscan2
- RNF17 | c.2557A>G p.I853V | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV55044147; called by muse, mutect2, varscan2
- SKA1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1287467675, COSV53279234; called by muse, mutect2, varscan2
- SLC16A4 | c.183G>C p.W61C | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767253783, COSV63916912; called by muse, mutect2, varscan2
- SLITRK5 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV61523949; called by muse, mutect2, varscan2
- SRPRB | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71749129; called by muse, mutect2, varscan2
- TGFBR1 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66625027, COSV66626174; called by muse, mutect2, varscan2
- TPR | c.6466C>T p.P2156S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV66602676; called by muse, mutect2, varscan2
- ZHX2 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58714532; called by muse, mutect2, varscan2
- BTBD11 | c.1938_1945del p.E647Pfs*53 (on ENST00000280758 / NM_001018072.2; = p.E184Pfs*53 on NM_001017523.2) | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- CLEC5A | c.306A>G p.K102= | Silent (SNP) | VAF 46/226 reads (20%) | catalogued as COSV69397556; called by muse, varscan2
- CPSF3 | c.1566C>G p.P522= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV53010463; called by muse, mutect2, varscan2
- GPR17 | c.579G>A p.P193= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as rs374867696; called by muse, mutect2, varscan2
- HNRNPR | c.600A>G p.P200= | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as COSV56422732; called by muse, mutect2
- PROKR1 | c.726G>T p.V242= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV58138218; called by muse, mutect2, varscan2
- SCGB2A2 | c.111G>C p.V37= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV57174744; called by muse, mutect2, varscan2
- SDK1 | c.897G>A p.P299= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs202239316, COSV101269768, COSV67363153, COSV67377139; called by muse, mutect2, varscan2
- STAT3 | c.1953T>C p.A651= | Silent (SNP) | VAF 114/376 reads (30%) | catalogued as COSV52889576; called by muse, mutect2, varscan2
